CCDI case PBCNDB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b74dbf4e-788a-4032-bae7-ec38438dfd7b

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.4 years (2,337 days).

Biospecimens (3 samples)
- Sample 0DVXF4: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DVXFJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DVXFO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
